Somatic mutation profile of tumor specimen ALCH-B34M-TTP1-A (aliquot ALCH-B34M-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B34M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.3 years (23,472 days).
Specimen ALCH-B34M-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b9d5beb-6367-447a-9201-1d76a1310dca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34M-NB1-A (Blood Derived Normal), aliquot ALCH-B34M-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/285019b7-e1b0-4532-a671-106e11394c2e

The open-access MAF lists 203 somatic variants for this specimen: 143 protein-altering or splice-affecting, 41 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 41, Intron 9, Nonsense Mutation 9, Frame Shift Del 7, Splice Site 6, 3'UTR 5, RNA 4, Splice Region 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 22/238 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2
- ANKRD26 | c.5051A>G p.D1684G | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs772007481, COSV65774259; called by muse, varscan2
- CDH18 | c.2225G>T p.G742V | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370841061; called by muse, mutect2, varscan2
- CDH9 | c.570C>A p.N190K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV99151415; called by muse, varscan2
- CLASP1 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1238245340; called by muse, mutect2
- COL12A1 | c.9182G>T p.G3061V | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1192211525; called by muse, mutect2
- COL3A1 | c.2000C>A p.A667E | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV58585651; called by muse, mutect2
- CPB1 | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51572290, COSV99294393; called by muse, mutect2, varscan2
- CPB1 | c.474+1G>T p.X158_splice | Splice Site (SNP) | VAF 7/61 reads (11%) | catalogued as rs756820249, COSV99294088; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs754135731; called by mutect2, varscan2*
- FBXW5 | c.392C>A p.A131E | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.197); catalogued as rs371500857; called by muse, mutect2, varscan2
- FGD2 | c.916C>G p.R306G | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs377492771, COSV51463112; called by muse, mutect2, varscan2
- HAS1 | c.813C>A p.N271K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752261227; called by muse, mutect2
- KIR2DL3 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.763); catalogued as COSV100667846; called by muse, mutect2
- KMT2E | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); catalogued as COSV99996143; called by muse, mutect2
- LGALS9 | c.875G>T p.R292L (on ENST00000395473 / NM_009587.3; = p.R260L on NM_002308.4) | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56350231; called by muse, mutect2
- LGR5 | c.1682G>T p.R561I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57005461, COSV57007412; called by muse, mutect2
- LHX9 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs1384500271, COSV61328702; called by muse, mutect2, varscan2
- LIG4 | c.2536C>T p.R846W | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs778998772, COSV63597660; called by muse, mutect2
- MYH11 | c.1823A>G p.N608S | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs750642581; ClinVar: uncertain significance; called by muse, mutect2
- MYO3A | c.4445G>T p.C1482F | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99779601; called by muse, mutect2, varscan2
- OR2T12 | c.536C>A p.A179D | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV58780154; called by muse, mutect2, varscan2
- OR4A15 | c.398C>A p.T133N | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as rs767078277; called by muse, mutect2
- OR4N5 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV61320830; called by muse, mutect2, varscan2
- OR56A4 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58109721; called by muse, mutect2, varscan2
- PCLO | c.3327C>A p.C1109* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV61653472; called by muse, mutect2
- PDZD2 | c.5037T>G p.H1679Q | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as rs374117473; called by muse, mutect2, varscan2
- PEG3 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV55647305, COSV55649110; called by muse, mutect2
- PIK3CG | c.3208G>C p.D1070H | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV100782636; called by muse, mutect2
- PPP1R3A | c.2081G>T p.S694I | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52885877; called by muse, mutect2
- PTPN20 | c.589T>G p.S197A | Missense Mutation (SNP) | VAF 27/479 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as rs1253333413; called by muse, mutect2
- PTPRE | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV54547347; called by muse, mutect2, varscan2
- RGPD3 | c.3299T>G p.M1100R | Missense Mutation (SNP) | VAF 62/561 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100450688; called by muse, mutect2, varscan2
- SEMA3A | c.1097G>T p.W366L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54867864; called by muse, mutect2, varscan2
- SPHK1 | c.596G>A p.R199H (on ENST00000392496 / NM_001355139.2; = p.R213H on NM_021972.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs17850292; called by muse, mutect2, varscan2
- SPOCK3 | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1330988651; called by muse, mutect2, varscan2
- TGFBI | c.1082A>G p.N361S | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283548556; called by muse, mutect2
- THBS4 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.978); catalogued as COSV63470990; called by muse, mutect2
- TIAF1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs757416941; called by muse, mutect2
- TMEFF2 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs376482759, COSV55829970; called by muse, mutect2, varscan2
- TMPRSS11A | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs748931509, COSV58359897; called by muse, mutect2, varscan2
- TNFAIP6 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.251); catalogued as COSV99693827; called by muse, mutect2
- TRAM1 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51600751; called by muse, mutect2
- TRANK1 | c.7136C>T p.P2379L | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs1233147217; called by muse, mutect2
- WDR64 | c.2590C>A p.R864S | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs764415019, COSV63799857; called by muse, mutect2, varscan2
- ZNF805 | c.1064G>T p.R355I | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs772650086, COSV62832817; called by muse, mutect2
- ABCA6 | c.2515G>C p.A839P | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ABCB5 | c.33A>T p.Q11H | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- ADCY2 | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.656); called by muse, varscan2
- ADGRL3 | c.610C>A p.P204T (on ENST00000506720 / NM_001322402.2; = p.P136T on NM_015236.6) | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANO3 | c.62A>T p.K21M | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- APOD | c.529A>T p.M177L | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ATRNL1 | c.3449C>A p.A1150E | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); called by muse, mutect2
- BMPER | c.319+3G>A | Splice Region (SNP) | VAF 24/282 reads (9%) | called by muse, mutect2
- BRINP2 | c.1902G>T p.R634S | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- CACNA1C | c.4687T>A p.F1563I | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2
- CAPN2 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CCDC83 | c.848C>A p.S283Y (on ENST00000342404 / NM_001286159.2; = p.S314Y on NM_173556.5) | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- CEBPZ | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- COL5A3 | c.1201G>T p.G401W | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPAMD8 | c.2902G>A p.V968M (on ENST00000651564; = p.V921M on NM_015692.5) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); called by muse, mutect2
- CR1 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.57); called by muse, mutect2
- CSN1S1 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CSN3 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.14); called by muse, mutect2
- CST3 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2
- DNAH12 | c.5449G>T p.G1817C (on ENST00000351747; = p.G1836C on NM_001366028.2) | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); called by muse, mutect2
- DSCAML1 | c.3679G>T p.V1227L (on ENST00000321322; = p.V1167L on NM_020693.4) | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- EIF4G1 | c.4155A>T p.K1385N (on ENST00000346169 / NM_198241.3; = p.K1190N on NM_004953.5) | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2
- ELMO1 | c.1823-1G>T p.X608_splice | Splice Site (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- EPHA7 | c.2270G>T p.R757M | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- EPRS1 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- FAM13C | c.1091G>C p.C364S | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- FAT4 | c.14323C>A p.P4775T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FLNC | c.2939T>A p.V980E | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FSIP2 | c.16478G>T p.S5493I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.199); called by muse, varscan2
- GIP | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GPRIN1 | c.1318del p.A440Qfs*40 | Frame Shift Del (DEL) | VAF 16/149 reads (11%) | called by mutect2, pindel, varscan2
- GREB1L | c.3401T>A p.M1134K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, varscan2
- HBG2 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 31/812 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HCFC1 | c.6047G>T p.R2016L | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- HERPUD1 | c.476T>C p.F159S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by mutect2, varscan2
- HERPUD1 | c.480del p.G161Vfs*26 | Frame Shift Del (DEL) | VAF 18/201 reads (9%) | called by mutect2, pindel
- HHLA2 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.047); called by muse, mutect2
- HNF4A | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- IFNA2 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- IGHV3-16 | c.121T>A p.C41S | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- ITGA5 | c.2243G>T p.R748L | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ITPR1 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM7A | c.1129A>G p.M377V | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2
- KRTAP5-6 | c.217T>G p.C73G | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.118); called by muse, mutect2
- LAMC3 | c.1746G>T p.L582F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- LCN15 | c.425C>A p.T142N | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.819); called by muse, mutect2
- LGR6 | c.1203del p.A402Pfs*28 (on ENST00000367278 / NM_001017403.1; = p.A350Pfs*28 on NM_021636.3) | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel
- LPA | c.5989T>A p.F1997I | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.91); called by muse, mutect2
- LRPPRC | c.1735+1G>T p.X579_splice | Splice Site (SNP) | VAF 32/401 reads (8%) | called by muse, mutect2
- LRRK1 | c.1173A>T p.K391N | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.049); called by muse, mutect2
- MICU3 | c.790T>G p.F264V | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2
- MRGPRE | c.522C>A p.C174* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- MUC2 | c.1940G>A p.W647* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- NACAD | c.4273G>C p.G1425R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV3 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NCOA3 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- NR1I2 | c.475A>G p.M159V | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- OR1C1 | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR1I1 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2
- OR2T6 | c.238A>T p.K80* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- OR4S2 | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.646); called by muse, mutect2
- OR6C76 | c.519C>A p.H173Q | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- OR8K5 | c.763C>A p.L255I | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- PCDHB15 | c.1487C>A p.P496Q | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.153); called by muse, mutect2
- PCNX3 | c.1430del p.G477Efs*28 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- POLR2B | c.2599A>G p.I867V | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PPP1R16B | c.946C>A p.H316N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- PSG4 | c.185T>A p.L62H | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2
- RBMS3 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); called by muse, mutect2
- RGS7 | c.*7-3C>A | Splice Region (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- RIMS1 | c.3482+1G>T p.X1161_splice | Splice Site (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- SDC2 | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by mutect2, varscan2
- SEPTIN4 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- SLAMF6 | c.508G>T p.G170* | Nonsense Mutation (SNP) | VAF 20/349 reads (6%) | called by muse, mutect2
- SLC4A11 | c.713A>T p.Q238L | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLCO6A1 | c.1226_1227del p.Y409Ffs*43 | Frame Shift Del (DEL) | VAF 13/130 reads (10%) | called by pindel, varscan2
- SLFN13 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); called by muse, varscan2
- SOHLH1 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STIL | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SYNE2 | c.13399C>G p.L4467V | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYT10 | c.1073_1074del p.T358Nfs*8 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- TF | c.1642G>C p.D548H | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- THEM5 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- THPO | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TKTL2 | c.1567G>C p.A523P | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPC4 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPV5 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); called by muse, mutect2
- WDFY3 | c.6719_6723del p.I2240Rfs*14 | Frame Shift Del (DEL) | VAF 28/279 reads (10%) | called by mutect2, pindel
- WDR49 | c.1544G>T p.G515V (on ENST00000308378 / NM_001366158.1; = p.G856V on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WNK4 | c.619-2A>T p.X207_splice | Splice Site (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- ZFAND1 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- ZFP57 | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFP57 | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF292 | c.4477G>T p.A1493S | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ZNF502 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- ZNF618 | c.511+1G>T p.X171_splice (on ENST00000374126 / NM_001318042.2; = p.X139_splice on NM_133374.2) | Splice Site (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- ADAM15 | c.939G>T p.T313= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- AMBRA1 | c.1881C>G p.P627= (on ENST00000458649 / NM_001367468.1; = p.P537= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- BDP1 | c.3204A>T p.G1068= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- BICDL2 | c.1212C>G p.L404= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- C4orf54 | c.5022C>A p.P1674= | Silent (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2277C>A p.V759= | Silent (SNP) | VAF 12/145 reads (8%) | called by muse, mutect2
- CSMD1 | c.2103T>G p.P701= (on ENST00000520002; = p.P700= on NM_033225.6) | Silent (SNP) | VAF 13/96 reads (14%) | called by muse, varscan2
- CYSLTR2 | c.507C>T p.S169= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as rs1219484462; called by muse, mutect2, varscan2
- DHX35 | c.861A>T p.V287= | Silent (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- DIP2C | c.4095G>T p.P1365= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as rs771830563, COSV55159931; called by muse, mutect2
- DNAH5 | c.11631C>T p.Y3877= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs776957889; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOC2A | c.301C>A p.R101= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV58751713; called by muse, mutect2, varscan2
- GAD2 | c.69C>T p.P23= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs1175743107, COSV52162371; called by muse, mutect2, varscan2
- GBP2 | c.1053G>T p.L351= | Silent (SNP) | VAF 14/280 reads (5%) | catalogued as COSV65069223; called by muse, mutect2
- GNA15 | c.33C>G p.P11= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- GPC2 | c.1662G>T p.G554= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV52786821; called by muse, mutect2, varscan2
- GPR107 | c.891G>T p.L297= | Silent (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- GRIK4 | c.1422C>A p.G474= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV70803287; called by muse, mutect2, varscan2
- GYPC | c.256C>A p.R86= | Silent (SNP) | VAF 28/247 reads (11%) | called by muse, mutect2, varscan2
- HMCN1 | c.8784G>T p.L2928= | Silent (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- KANSL1 | c.942G>A p.E314= | Silent (SNP) | VAF 8/189 reads (4%) | called by muse, mutect2
- KCTD16 | c.183G>T p.T61= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as rs766844514; called by muse, mutect2
- LARP4B | c.576A>C p.T192= | Silent (SNP) | VAF 13/271 reads (5%) | called by muse, mutect2
- LPAR1 | c.207G>A p.L69= | Silent (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- MAP3K21 | c.2565T>C p.L855= | Silent (SNP) | VAF 25/213 reads (12%) | called by muse, mutect2, varscan2
- MTBP | c.1905A>T p.T635= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- MYO10 | c.5712G>A p.E1904= | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2
- NPHP1 | c.1953G>T p.T651= (on ENST00000393272 / NM_207181.4; = p.T652= on NM_000272.5) | Silent (SNP) | VAF 46/294 reads (16%) | called by muse, mutect2, varscan2
- NRIP2 | c.219T>C p.L73= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2, varscan2
- OPRK1 | c.495G>A p.K165= | Silent (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- OR10C1 | c.786C>A p.R262= (on ENST00000622521; = p.R260= on NM_013941.3) | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- OR1Q1 | c.579C>T p.Y193= | Silent (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- PCDH15 | c.4953G>C p.L1651= (on ENST00000644397 / NM_001354429.2; = p.L1593= on NM_001142771.2) | Silent (SNP) | VAF 72/440 reads (16%) | catalogued as COSV64704947; called by muse, mutect2, varscan2
- PGLYRP3 | c.441G>A p.K147= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs1167912605; called by muse, mutect2
- PRKD1 | c.840G>T p.R280= | Silent (SNP) | VAF 14/270 reads (5%) | catalogued as rs1566505296; called by muse, mutect2
- SLC4A3 | c.1260C>T p.T420= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs770803610; called by mutect2, varscan2
- SYK | c.894C>T p.F298= | Silent (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- UBAP2L | c.2538G>T p.L846= | Silent (SNP) | VAF 28/258 reads (11%) | called by muse, mutect2, varscan2
- UGT1A8 | c.489C>T p.L163= | Silent (SNP) | VAF 14/290 reads (5%) | catalogued as COSV65078543; called by muse, mutect2
- UNC5D | c.1296C>G p.V432= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- ZNF521 | c.579A>G p.L193= | Silent (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- AC114490.3 | c.*705C>T | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- AC244394.2 | n.1535C>A | RNA (SNP) | VAF 7/51 reads (14%) | called by mutect2, varscan2
- ACTN2 | c.*30C>T | 3'UTR (SNP) | VAF 10/203 reads (5%) | catalogued as COSV100856941; called by muse, mutect2
- AMPH | c.1183-1172G>T | Intron (SNP) | VAF 8/173 reads (5%) | called by muse, mutect2
- COPG1 | c.872-12A>G | Intron (SNP) | VAF 5/31 reads (16%) | catalogued as rs1334862177; called by muse, mutect2, varscan2
- CPLANE1 | c.*4026A>G | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- CPLANE1 | c.*4025T>A | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- CRACR2B | c.693+92G>T | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- CTSK | c.399+38G>T | Intron (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- FAM183BP | n.897G>A | RNA (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- HPS5 | c.3330-672A>T | Intron (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- IGHMBP2 | c.-9G>T | 5'UTR (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- MIR1202 | n.40C>A | RNA (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- OR56B3P | n.212T>A | RNA (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- PNPLA7 | c.31-196C>T | Intron (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- SLC1A3 | c.181+4260C>A | Intron (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- SSX5 | c.69+187T>C | Intron (SNP) | VAF 10/175 reads (6%) | called by muse, mutect2
- TKFC | c.566-23C>T | Intron (SNP) | VAF 15/166 reads (9%) | called by muse, mutect2
- TMEM135 | c.*6573T>A | 3'UTR (SNP) | VAF 32/357 reads (9%) | called by muse, mutect2
